Somatic mutation profile of tumor specimen C3N-02451-03 (aliquot CPT0241040006) from CPTAC case C3N-02451, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 78.2 years (28,546 days).
Specimen C3N-02451-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be142abb-f7b2-4c85-986e-380644ceb8d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02451-31 (Blood Derived Normal), aliquot CPT0241800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bba9bb2-b534-46f7-9f24-8c12d7cbfe55

The open-access MAF lists 111 somatic variants for this specimen: 83 protein-altering or splice-affecting, 14 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 14, Intron 5, Frame Shift Del 4, Nonsense Mutation 4, 3'UTR 3, Splice Region 2, Splice Site 2, 5'UTR 2, In Frame Del 2, RNA 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 122/494 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 36/238 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CD1B | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs756501763; called by muse, mutect2, varscan2
- COL11A1 | c.3555G>T p.E1185D | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as COSV100615975; called by muse, mutect2
- EIF2AK1 | c.317_319del p.S106del | In Frame Del (DEL) | VAF 24/140 reads (17%) | catalogued as rs1270746869; called by pindel, varscan2
- FAM83B | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs768677387, COSV60923191; called by muse, mutect2, varscan2
- GABRA6 | c.1258T>A p.Y420N | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV50888711; called by muse, mutect2, varscan2
- GPC5 | c.1371G>C p.Q457H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as rs1372765434; called by muse, mutect2, varscan2
- ITGB4 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 66/682 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751173051; called by muse, mutect2
- KHDRBS2 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1408764252, COSV55468978; called by muse, mutect2, varscan2
- LYST | c.3845G>C p.S1282T | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV67713216; called by muse, mutect2, varscan2
- MBL2 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV64759244; called by muse, mutect2, varscan2
- MDGA2 | c.973C>G p.P325A (on ENST00000399232 / NM_001113498.2; = p.P27A on NM_182830.4) | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV62081581; called by muse, mutect2, varscan2
- MTHFR | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs754554624, CM035840; called by muse, mutect2, varscan2
- MYH14 | c.4867G>A p.D1623N | Missense Mutation (SNP) | VAF 25/306 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV51831469; called by muse, mutect2
- NALCN | c.2758-1G>C p.X920_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV51958342; called by muse, mutect2, varscan2
- NELFCD | c.861G>T p.Q287H (on ENST00000602795; = p.Q269H on NM_198976.4) | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as COSV99413728; called by mutect2, varscan2
- NR1I2 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs142454025; called by muse, mutect2, varscan2
- OR2D3 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV53496212; called by muse, mutect2, varscan2
- OR4S1 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV100180151; called by muse, mutect2, varscan2
- PCDHGA7 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs772901140, COSV99533587; called by muse, mutect2
- RABGEF1 | c.785C>T p.T262M (on ENST00000439720 / NM_001287061.2; = p.T249M on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as rs773885514; called by muse, mutect2, varscan2
- RBM10 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 70/317 reads (22%) | catalogued as COSV61308134; called by muse, mutect2, varscan2
- RBMXL3 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 56/584 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs782576147, COSV57750145; called by muse, mutect2
- RPS6KA6 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 26/201 reads (13%) | catalogued as COSV53116827, COSV53121021; called by muse, mutect2, varscan2
- RSL1D1 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 99/426 reads (23%) | catalogued as rs766501222, COSV63077384, COSV63077443; called by muse, mutect2, varscan2
- SLC35B2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs763046871, COSV51488711; called by muse, mutect2, varscan2
- SLITRK5 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs761739717; called by muse, mutect2, varscan2
- SMARCC2 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs144543721; called by muse, mutect2
- SPCS2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs1305630078; called by muse, mutect2, varscan2
- TMEM131 | c.5128G>A p.V1710I | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750202724, COSV51779319; called by muse, mutect2
- ZNF280A | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs780225696, COSV57480372; called by muse, mutect2, varscan2
- ABCA13 | c.3656C>G p.A1219G | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ADGB | c.4790A>G p.E1597G | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2
- ARF5 | c.67+3G>A | Splice Region (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ATAD3A | c.1441C>A p.L481M | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA1E | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALCRL | c.902C>G p.A301G | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH12 | c.350_352del p.L117_D118delinsH | In Frame Del (DEL) | VAF 54/236 reads (23%) | called by mutect2, pindel, varscan2
- CLSPN | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL12A1 | c.5000C>T p.T1667I | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- COL3A1 | c.4255-1G>C p.X1419_splice | Splice Site (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- COL4A3 | c.1235A>C p.D412A | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.825); called by muse, mutect2
- DCC | c.2078del p.S693Ifs*7 | Frame Shift Del (DEL) | VAF 29/227 reads (13%) | called by mutect2, pindel, varscan2
- DNAAF6 | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- DSP | c.7351A>C p.K2451Q | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FRMD8 | c.14A>C p.E5A | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, varscan2
- FRMD8 | c.20_32del p.S7Tfs*26 | Frame Shift Del (DEL) | VAF 27/256 reads (11%) | called by pindel, varscan2
- GCNT7 | c.466G>C p.G156R | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPC4 | c.936G>T p.M312I | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.326); called by muse, mutect2
- H2AC20 | c.94C>G p.H32D | Missense Mutation (SNP) | VAF 182/634 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMCN1 | c.14959G>C p.D4987H | Missense Mutation (SNP) | VAF 51/549 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA5 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.758); called by muse, mutect2
- ILRUN | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- INF2 | c.3573G>C p.K1191N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KCNA5 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL2 | c.254T>G p.F85C | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAD1 | c.1248G>A p.R416= | Splice Region (SNP) | VAF 99/327 reads (30%) | called by muse, mutect2, varscan2
- NLRP5 | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NRK | c.3003C>G p.C1001W | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- OR1S1 | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PRDM7 | c.121G>C p.A41P | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PRORP | c.1147T>C p.Y383H | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- RPA1 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2
- S1PR3 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC2A13 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- SMARCAD1 | c.1124G>C p.S375T | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SSTR2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 43/464 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.773); called by muse, mutect2
- SYMPK | c.2158_2168del p.L720* | Frame Shift Del (DEL) | VAF 25/195 reads (13%) | called by mutect2, pindel, varscan2
- SYP | c.506T>C p.M169T | Missense Mutation (SNP) | VAF 36/365 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D19 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- TCEAL6 | c.471del p.M159Wfs*30 | Frame Shift Del (DEL) | VAF 29/264 reads (11%) | called by mutect2, varscan2
- TENM3 | c.6139G>C p.D2047H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TSPAN8 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.3373G>A p.G1125R (on ENST00000591111; = p.G1079R on NM_003319.4) | Missense Mutation (SNP) | VAF 28/322 reads (9%) | PolyPhen probably damaging (1); called by muse, mutect2
- UNC93B1 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- VBP1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- WDR46 | c.1685C>A p.T562K | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YIF1B | c.83C>T p.S28F (on ENST00000339413 / NM_001039673.3; = p.S13F on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.564); called by muse, mutect2
- YTHDF1 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ZMIZ1 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF441 | c.505T>A p.Y169N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZNF536 | c.3718C>G p.Q1240E | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD50 | c.1407G>A p.A469= | Silent (SNP) | VAF 21/184 reads (11%) | catalogued as rs553953140, COSV101539016; called by muse, mutect2, varscan2
- ATP10B | c.2187C>T p.H729= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as rs761911543, COSV100515649, COSV59168554; called by muse, mutect2
- BASP1 | c.147C>T p.A49= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as rs779751947; called by muse, mutect2, varscan2
- DEDD2 | c.306G>C p.L102= | Silent (SNP) | VAF 27/262 reads (10%) | called by muse, mutect2, varscan2
- ITIH6 | c.2121T>A p.I707= | Silent (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- KIAA0232 | c.3978T>C p.S1326= | Silent (SNP) | VAF 16/155 reads (10%) | called by muse, mutect2, varscan2
- MAP3K15 | c.249G>A p.A83= | Silent (SNP) | VAF 46/276 reads (17%) | called by muse, mutect2, varscan2
- NAPRT | c.132C>T p.F44= | Silent (SNP) | VAF 13/167 reads (8%) | catalogued as rs1406635308; called by muse, mutect2
- PCDHB8 | c.1749G>A p.P583= | Silent (SNP) | VAF 105/1138 reads (9%) | catalogued as rs782067091; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1596C>T p.A532= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs778467297, COSV50248798; called by muse, mutect2, varscan2
- RASIP1 | c.804C>T p.F268= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- SLC14A1 | c.1053C>A p.I351= | Silent (SNP) | VAF 33/228 reads (14%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.4230G>A p.R1410= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs556880034; called by muse, mutect2, varscan2
- ZHX3 | c.1896A>G p.A632= | Silent (SNP) | VAF 19/241 reads (8%) | called by muse, mutect2
- C4orf50 | c.-288A>T | 5'UTR (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- CDH8 | c.*782G>T | 3'UTR (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- DEPDC4 | c.879-1129A>G | Intron (SNP) | VAF 21/90 reads (23%) | catalogued as rs1359097424; called by muse, mutect2, varscan2
- LDHA | chr11:18394595 C>T | 5'Flank (SNP) | VAF 50/413 reads (12%) | catalogued as rs1016376653; called by muse, mutect2, varscan2
- MIR600 | n.39T>A | RNA (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- MT4 | c.-12G>T | 5'UTR (SNP) | VAF 33/341 reads (10%) | called by muse, mutect2
- PCDH11X | c.3033+3663C>A | Intron (SNP) | VAF 7/174 reads (4%) | catalogued as rs1227747000, COSV53462519; called by muse, mutect2
- PSCA | c.*272T>C | 3'UTR (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- PTGES3 | c.2+62C>A | Intron (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49892380 C>T | 5'Flank (SNP) | VAF 31/253 reads (12%) | catalogued as rs748424641; called by muse, mutect2, varscan2
- SORBS2 | c.-46+933C>G | Intron (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.575C>T | RNA (SNP) | VAF 18/133 reads (14%) | catalogued as rs764190440; called by muse, mutect2, varscan2
- VWF | c.*33C>T | 3'UTR (SNP) | VAF 36/243 reads (15%) | catalogued as rs1185152044, COSV99778124; called by muse, mutect2, varscan2
- ZC3HC1 | c.146+771G>A | Intron (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
